Somatic mutation profile of tumor specimen MP2PRT-PATVVA-TMP1-A (aliquot MP2PRT-PATVVA-TMP1-A-1-0-D-A81P-36) from MP2PRT case MP2PRT-PATVVA, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.2 years (1,179 days).
Specimen MP2PRT-PATVVA-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f77458bd-f593-40b9-bb4d-9fcccf453e4c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PATVVA-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PATVVA-NB1-A-1-0-D-A81P-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/92c71428-869f-4c7a-be03-411adfed9801

The open-access MAF lists 15 somatic variants for this specimen: 11 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 8, Silent 4, Nonsense Mutation 2, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1900G>A p.D634N (on ENST00000288602 / NM_001374244.1; = p.D594N on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 51/129 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.267); catalogued as rs397516896, COSV56061673, COSV56106240, COSV56184663; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- NRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 94/202 reads (47%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen benign (0.323); catalogued as rs121434596, CM071907, COSV54736416, COSV54736480, COSV54736793; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- CLDN18 | c.238C>T p.R80* | Nonsense Mutation (SNP) | VAF 77/194 reads (40%) | catalogued as rs761116930, COSV51736198, COSV51737856; called by muse, mutect2, varscan2
- ETV1 | c.637C>T p.R213C | Missense Mutation (SNP) | VAF 82/231 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.159); catalogued as rs772105404, COSV54136587; called by muse, mutect2, varscan2
- FTMT | c.416G>A p.R139Q | Missense Mutation (SNP) | VAF 17/376 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.093); catalogued as COSV58420675; called by muse, mutect2
- PPP4R4 | c.247C>T p.R83* | Nonsense Mutation (SNP) | VAF 110/498 reads (22%) | catalogued as rs1268987676, COSV58558132; called by muse, mutect2, varscan2
- RIPOR3 | c.466G>A p.A156T | Missense Mutation (SNP) | VAF 178/403 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.704); catalogued as rs779928609; called by muse, varscan2
- SPACA1 | c.94G>A p.V32I | Missense Mutation (SNP) | VAF 204/630 reads (32%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.122); catalogued as COSV52759515; called by muse, mutect2, varscan2
- USP16 | c.1123-1G>A p.X375_splice | Splice Site (SNP) | VAF 36/285 reads (13%) | catalogued as COSV100538053; called by muse, mutect2, varscan2
- IRAK4 | c.505T>A p.S169T | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT tolerated (0.45); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PLXNC1 | c.1411C>T p.H471Y | Missense Mutation (SNP) | VAF 66/163 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- AMIGO2 | c.1023C>T p.Y341= | Silent (SNP) | VAF 133/267 reads (50%) | catalogued as rs779114672; called by muse, mutect2, varscan2
- LRP2 | c.11238A>G p.G3746= | Silent (SNP) | VAF 96/175 reads (55%) | called by muse, mutect2, varscan2
- NLGN3 | c.879C>T p.C293= (on ENST00000358741 / NM_181303.2; = p.C273= on NM_018977.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 45/373 reads (12%) | catalogued as rs745489501; called by muse, mutect2, varscan2
- TMPRSS15 | c.2019T>C p.D673= | Silent (SNP) | VAF 70/407 reads (17%) | called by muse, mutect2, varscan2
